Somatic mutation profile of tumor specimen MMRF_1665_1_BM_CD138pos (aliquot MMRF_1665_1_BM_CD138pos_T1_KBS5U_L04403) from MMRF case MMRF_1665, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.6 years (23,597 days).
Specimen MMRF_1665_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b45fb397-109f-499f-969d-5a2bfc85224a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1665_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1665_1_PB_Whole_C3_KBS5U_L04407; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41889d7c-e383-4c31-a75f-717e067837cb

The open-access MAF lists 164 somatic variants for this specimen: 68 protein-altering or splice-affecting, 19 silent, 77 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, 3'UTR 46, Silent 19, Intron 16, 5'UTR 6, 3'Flank 4, 5'Flank 4, Frame Shift Del 3, Nonsense Mutation 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ELN | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1064793880, CM093575, COSV52708187; ClinVar: pathogenic; called by muse, mutect2
- ABCC9 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.608); catalogued as rs200349671, CM141606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS16 | c.1492G>T p.V498L | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs112925528; called by muse, mutect2, varscan2
- C4A | c.3163C>T p.R1055W | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs750422695; called by muse, mutect2, varscan2
- CLPSL1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs367548710; called by muse, mutect2
- DBH | c.805T>C p.C269R | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1193871229; called by muse, mutect2
- DHRS9 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV59139195; called by muse, mutect2, varscan2
- DLK1 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs749760314, COSV57990669; called by muse, mutect2, varscan2
- FBXL7 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61649228; called by muse, mutect2
- GALNT17 | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs760801965, COSV61165340; called by muse, mutect2, varscan2
- GDA | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.037); catalogued as rs201400872; called by muse, mutect2, varscan2
- HAS1 | c.1555C>T p.R519C | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.585); catalogued as COSV55788543; called by muse, mutect2, varscan2
- IGHV1-24 | c.160C>T p.H54Y | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as rs1555470141; called by muse, varscan2
- IGHV1-69 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as rs544777113; called by muse, mutect2, varscan2
- IGKV4-1 | c.359C>G p.T120S | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs749276071; called by muse, mutect2, varscan2
- IGLV3-1 | c.200A>T p.Y67F | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs375057861; called by muse, varscan2
- LAMA5 | c.8929G>A p.G2977R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53372603; called by muse, mutect2, varscan2
- LYN | c.387G>T p.W129C | Missense Mutation (SNP) | VAF 104/228 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70206133; called by muse, mutect2, varscan2
- MAGI3 | c.2837del p.G946Efs*31 | Frame Shift Del (DEL) | VAF 35/93 reads (38%) | catalogued as COSV100289791; called by mutect2, pindel, varscan2
- MATK | c.182G>A p.R61H (on ENST00000310132 / NM_139355.3; = p.R62H on NM_002378.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.832); catalogued as rs762544633; called by muse, varscan2
- MYH9 | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs760924443, COSV53393158; called by muse, mutect2, varscan2
- NEURL4 | c.2213G>A p.R738H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201553991; called by muse, mutect2, varscan2
- NPAS1 | c.1618G>A p.G540S | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); catalogued as rs992359895; called by muse, mutect2
- PDCD11 | c.2597G>A p.G866E | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV63934898; called by muse, mutect2, varscan2
- PTPRD | c.4487G>A p.R1496Q | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772303653, COSV61934500; called by muse, mutect2, varscan2
- RNF10 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs1329528762, COSV58047872; called by muse, mutect2
- RYR1 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.707); catalogued as rs757908433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.3442G>A p.V1148I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.917); catalogued as rs201174268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNAP91 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.188); catalogued as rs1407466799, COSV52125838; called by muse, mutect2, varscan2
- TULP2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.258); catalogued as rs1426703043; called by muse, mutect2, varscan2
- UBR2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1417286282, COSV65769651; called by muse, mutect2, varscan2
- ZNF469 | c.4802G>A p.R1601H (on ENST00000437464; = p.R1629H on NM_001367624.2) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as rs780466908; called by mutect2, varscan2
- AC063943.2 | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACAP1 | c.1468del p.E490Rfs*5 | Frame Shift Del (DEL) | VAF 12/17 reads (71%) | called by mutect2, pindel, varscan2
- ATP13A5 | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 21/210 reads (10%) | called by muse, mutect2
- C1orf56 | c.289T>C p.S97P | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C1orf87 | c.1387G>T p.A463S | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CACNA2D1 | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 108/199 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CAMK1D | c.1129G>T p.V377L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- CCDC39 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CKAP2 | c.1997T>G p.V666G (on ENST00000378037 / NM_001098525.2; = p.V665G on NM_018204.5) | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2
- COL4A1 | c.760T>C p.F254L | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DACH1 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- FAM186A | c.524T>G p.I175R | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- FBXO4 | c.895_898+1del p.X299_splice | Splice Site (DEL) | VAF 37/184 reads (20%) | called by mutect2, pindel*, varscan2
- GABRA2 | c.319C>G p.P107A | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- H4C13 | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.269); called by muse, mutect2, varscan2
- IGHV1-24 | c.337T>G p.Y113D | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- IGHV1-24 | c.262A>C p.T88P | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- IGHV2-70 | c.152_155delinsCTAA p.S51_G52delinsTK | Missense Mutation (ONP) | VAF 4/26 reads (15%) | called by muse*, pindel
- KBTBD12 | c.737G>C p.C246S | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNC1 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA0100 | c.5831A>C p.K1944T | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- LRRCC1 | c.1643A>C p.E548A | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- MMP24 | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MUC12 | c.1792G>T p.G598C (on ENST00000379442; = p.G455C on NM_001164462.1) | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2
- MUC17 | c.5620G>C p.V1874L | Missense Mutation (SNP) | VAF 143/503 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NSUN3 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PHF8 | c.1150G>A p.E384K (on ENST00000357988 / NM_001184896.1; = p.E348K on NM_015107.3) | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- PIH1D1 | c.460T>A p.Y154N | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SAXO1 | c.642C>A p.H214Q | Missense Mutation (SNP) | VAF 85/320 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SPANXN3 | c.160G>C p.V54L | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SSTR1 | c.21del p.S8Pfs*44 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | called by mutect2, pindel, varscan2
- TMEM40 | c.439T>C p.S147P | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- UAP1 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- UNC5CL | c.12G>T p.Q4H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); called by muse, mutect2
- ZNF462 | c.1387T>A p.L463I | Missense Mutation (SNP) | VAF 15/151 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF585B | c.1664G>T p.C555F | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ARHGEF18 | c.1776A>G p.K592= (on ENST00000359920 / NM_001130955.2; = p.K488= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/204 reads (22%) | called by muse, mutect2, varscan2
- DPP6 | c.1330C>A p.R444= (on ENST00000377770 / NM_001364500.2; = p.R382= on NM_001936.5) | Silent (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- FRZB | c.93G>T p.R31= | Silent (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- GALNT12 | c.906C>T p.V302= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as rs375005028; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGLV1-44 | c.177C>A p.L59= | Silent (SNP) | VAF 68/164 reads (41%) | called by muse, mutect2, varscan2
- LRWD1 | c.720C>T p.L240= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV52960486, COSV52962281; called by muse, mutect2, varscan2
- MAPT | c.1917C>T p.P639= (on ENST00000262410 / NM_001377265.1; = p.P247= on NM_005910.5) | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs563586090; called by muse, mutect2, varscan2
- MIPEP | c.1896T>C p.Y632= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs77219429; called by muse, mutect2, varscan2
- PEX14 | c.816G>A p.T272= | Silent (SNP) | VAF 64/164 reads (39%) | catalogued as rs572028093; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF152 | c.237C>T p.I79= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as rs750723774, COSV100455120; called by muse, mutect2, varscan2
- SHTN1 | c.396C>T p.A132= | Silent (SNP) | VAF 22/157 reads (14%) | catalogued as rs575263703; called by muse, mutect2, varscan2
- SORCS1 | c.2916A>G p.V972= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV53842214; called by muse, mutect2, varscan2
- SPIB | c.399C>T p.D133= | Silent (SNP) | VAF 54/98 reads (55%) | catalogued as rs776379228; called by muse, varscan2
- TAS2R4 | c.207C>T p.F69= | Silent (SNP) | VAF 16/233 reads (7%) | catalogued as rs147698747; called by muse, mutect2
- TEX264 | c.450T>C p.R150= | Silent (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- TRAF3IP1 | c.702A>G p.R234= | Silent (SNP) | VAF 5/25 reads (20%) | called by muse, mutect2, varscan2
- TTC1 | c.357A>G p.L119= | Silent (SNP) | VAF 132/300 reads (44%) | called by muse, mutect2, varscan2
- TTF1 | c.102C>T p.H34= | Silent (SNP) | VAF 40/330 reads (12%) | catalogued as rs1485817641, COSV57507616; called by muse, mutect2, varscan2
- TTLL5 | c.2163A>T p.R721= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- ATPAF1 | chr1:46634946 A>T | 3'Flank (SNP) | VAF 31/78 reads (40%) | called by muse, mutect2, varscan2
- B3GLCT | c.*1642T>C | 3'UTR (SNP) | VAF 25/56 reads (45%) | catalogued as rs1222111108; called by muse, mutect2, varscan2
- BMPR2 | c.*2468A>G | 3'UTR (SNP) | VAF 49/89 reads (55%) | called by muse, mutect2, varscan2
- C18orf21 | c.*120G>A | 3'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- C6orf136 | chr6:30647065 G>A | 5'Flank (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- C6orf201 | c.*24del | 3'UTR (DEL) | VAF 70/488 reads (14%) | called by mutect2, pindel, varscan2
- C8orf31 | n.758del | RNA (DEL) | VAF 30/307 reads (10%) | called by mutect2, pindel, varscan2
- CAMSAP1 | c.*2033G>A | 3'UTR (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2, varscan2
- CARF | c.832+433A>T | Intron (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- CDH12 | c.*790_*791insAGAAAA | 3'UTR (INS) | VAF 38/82 reads (46%) | catalogued as rs747886374; called by mutect2, varscan2
- CDH2 | c.*271A>C | 3'UTR (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- CGGBP1 | c.*5G>A | 3'UTR (SNP) | VAF 11/199 reads (6%) | called by muse, mutect2
- CHL1 | chr3:407953 A>G | 3'Flank (SNP) | VAF 112/178 reads (63%) | called by muse, mutect2, varscan2
- CRACD | c.*658C>A | 3'UTR (SNP) | VAF 63/145 reads (43%) | called by muse, mutect2, varscan2
- CTRB1 | c.53-62C>T | Intron (SNP) | VAF 10/24 reads (42%) | catalogued as rs535819414; called by muse, varscan2
- DENND3 | c.*1049C>T | 3'UTR (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- DENND5A | c.*239T>G | 3'UTR (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2
- EIF2B1 | c.*541G>C | 3'UTR (SNP) | VAF 34/63 reads (54%) | called by muse, mutect2, varscan2
- EIF3A | c.*656T>C | 3'UTR (SNP) | VAF 50/132 reads (38%) | called by muse, mutect2, varscan2
- ERCC6L2 | c.2100+1650C>G | Intron (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- ETFBKMT | c.*3077C>T | 3'UTR (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2
- FFAR4 | c.*248G>A | 3'UTR (SNP) | VAF 25/39 reads (64%) | called by muse, mutect2, varscan2
- FGF23 | c.*562T>C | 3'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- FGFR4 | c.*240T>G | 3'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- GCLC | c.1401+96A>G | Intron (SNP) | VAF 144/352 reads (41%) | called by muse, mutect2, varscan2
- GIN1 | c.*75G>A | 3'UTR (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2
- HTR3D | c.*10C>A | 3'UTR (SNP) | VAF 22/385 reads (6%) | called by muse, mutect2
- IFRD2 | chr3:50292783 G>A | 5'Flank (SNP) | VAF 39/200 reads (20%) | catalogued as rs367629111; called by muse, mutect2, varscan2
- IGF2BP3 | c.*203C>A | 3'UTR (SNP) | VAF 16/320 reads (5%) | called by muse, mutect2
- IGHV3-23 | c.-75C>G | 5'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- IGSF1 | c.-5G>T | 5'UTR (SNP) | VAF 39/45 reads (87%) | called by muse, mutect2, varscan2
- KCNMB1 | c.306+876C>G | Intron (SNP) | VAF 38/163 reads (23%) | called by muse, mutect2, varscan2
- KLHL7 | c.-211A>T | 5'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- KLHL9 | c.*570G>A | 3'UTR (SNP) | VAF 52/83 reads (63%) | called by muse, mutect2, varscan2
- LTB | c.209-78C>A | Intron (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- MARK1 | c.-34C>T | 5'UTR (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- MFAP3L | c.*1157G>A | 3'UTR (SNP) | VAF 27/74 reads (36%) | called by muse, mutect2, varscan2
- MTMR9 | c.*2151A>T | 3'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2
- NCAM2 | c.*1198C>A | 3'UTR (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- NDC1 | chr1:53838429 C>A | 5'Flank (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- NEBL-AS1 | chr10:21173803 C>G | 5'Flank (SNP) | VAF 25/139 reads (18%) | catalogued as rs371100252; called by muse, varscan2
- NRG3 | chr10:82985976 G>A | 3'Flank (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- NTRK3 | c.*7366C>A | 3'UTR (SNP) | VAF 24/109 reads (22%) | called by muse, mutect2, varscan2
- OGA | c.1984+246A>C | Intron (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- PARD3 | c.*649G>T | 3'UTR (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- PCDH15 | c.3374-1837C>T | Intron (SNP) | VAF 17/131 reads (13%) | catalogued as rs751247448, COSV100224746; called by muse, mutect2, varscan2
- PDE1A | c.-10-116A>G | Intron (SNP) | VAF 65/151 reads (43%) | called by muse, mutect2, varscan2
- PIK3R3 | c.*282A>T | 3'UTR (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- PLCB1 | c.*2439A>G | 3'UTR (SNP) | VAF 10/97 reads (10%) | called by muse, mutect2, varscan2
- PLSCR4 | c.*876G>A | 3'UTR (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- PLXNA4 | c.*1208T>C | 3'UTR (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- POU2F1 | c.-8-3356T>C | Intron (SNP) | VAF 33/87 reads (38%) | called by muse, mutect2, varscan2
- PPP1R3C | c.*1325A>C | 3'UTR (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- PRLR | c.*1535G>C | 3'UTR (SNP) | VAF 14/145 reads (10%) | called by muse, mutect2
- PRPF39 | c.451-300T>G | Intron (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- RAB11FIP3 | c.903+3657G>T | Intron (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- RAB17 | c.*73A>T | 3'UTR (SNP) | VAF 46/86 reads (53%) | called by muse, mutect2, varscan2
- RBM4B | c.-12-103T>C | Intron (SNP) | VAF 53/200 reads (27%) | called by muse, mutect2, varscan2
- RNF157 | c.*1634C>A | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2
- SERPINB4 | c.*183C>A | 3'UTR (SNP) | VAF 30/678 reads (4%) | catalogued as rs1168621352; called by muse, mutect2
- SLC6A15 | c.*1442A>T | 3'UTR (SNP) | VAF 52/113 reads (46%) | catalogued as rs1454467646; called by muse, mutect2, varscan2
- SLIT3 | c.*3652G>A | 3'UTR (SNP) | VAF 28/142 reads (20%) | called by muse, mutect2, varscan2
- SLITRK2 | c.-4215A>T | 5'UTR (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20318634 G>T | 3'Flank (SNP) | VAF 29/220 reads (13%) | called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3090+30C>T | Intron (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- SYBU | c.*823A>G | 3'UTR (SNP) | VAF 82/166 reads (49%) | called by muse, mutect2, varscan2
- TCF7L2 | c.*1081C>T | 3'UTR (SNP) | VAF 16/172 reads (9%) | catalogued as rs1055504987; called by muse, mutect2
- TMEM213 | c.*1059A>C | 3'UTR (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- TMEM30A | c.*464A>G | 3'UTR (SNP) | VAF 44/97 reads (45%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+73_-17+75del | Intron (DEL) | VAF 64/78 reads (82%) | called by mutect2, pindel, varscan2
- TPRG1 | c.*623C>T | 3'UTR (SNP) | VAF 55/160 reads (34%) | called by muse, mutect2, varscan2
- TRIM66 | c.*3488C>T | 3'UTR (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- TSC2 | c.2967-89G>A | Intron (SNP) | VAF 3/15 reads (20%) | catalogued as rs1264878833; called by muse, mutect2
- UBE3A | c.*642G>A | 3'UTR (SNP) | VAF 12/87 reads (14%) | catalogued as rs1031963863; called by muse, mutect2, varscan2
- VHLL | c.-68G>A | 5'UTR (SNP) | VAF 3/8 reads (38%) | catalogued as rs1474493257; called by muse, mutect2
- ZCCHC14 | c.*3628G>A | 3'UTR (SNP) | VAF 10/59 reads (17%) | catalogued as rs536209034; called by muse, mutect2, varscan2
- ZNF516 | c.*408G>A | 3'UTR (SNP) | VAF 48/101 reads (48%) | called by muse, mutect2, varscan2
